Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6458, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6458-01A (Primary Tumor).

		STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Fundus Tumor size: 0 x 0 x 8.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 1/15 positive for metastasis (Greater and lesser omentum 1/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	--	--

11

Source: NCI Genomic Data Commons file 9d4de1c4-c1fd-4510-bc1b-c736dc5c150a (TCGA-BR-6458.F8162F79-5A2D-4B69-877B-F7E796DC57B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).